Gene-level copy-number profile of tumor specimen C3L-03381-03 from CPTAC case C3L-03381, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 79.0 years (28,844 days).
Specimen C3L-03381-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f1735ca5-1279-446c-8c4c-7078e187c6aa.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03381-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,705 have no estimate.
https://portal.gdc.cancer.gov/files/371140a2-99c0-49cc-b163-0ddb9dde8572

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 532; copy number 1: 3,669; copy number 2: 46,849; copy number 3: 7,443; copy number 4: 425.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,345. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
